Surgical pathology report (de-identified scan), TCGA case TCGA-VR-A8EP, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-A8EP-01A (Primary Tumor).

ICD-O-3

Carcinoma, squamous cell NOS 8070/3

Site Esophagus, middle third C15.4

W 1/24/14

Collect date:

(MM/DD/YYYY)

PRIMARY SITE: Esophagus (Mid third)

PATHOLOGY REPORT:

1 - "Esophagectomy specimen":

- Specimen: esophagus and proximal stomach
- Procedure: esophagogastrectomy
- Tumor site: esophagus
- Tumor size (greatest dimension): 6.2 cm
- Histologic type: squamous cell carcinoma.
- Histologic grade: G3, poorly differentiated.
- Microscopic tumor extension: tumor invades through muscularis propria into the periesophageal fat tissue.
- Lymph-vascular invasion: present
- Perineural invasion: present
- Margins uninvolved by carcinoma
- Gastric mucosa exhibit moderate chronic gastritis with lymphoid follicular hyperplasia, uninvolved by carcinoma
- Esophagus segment without neoplasia demonstrated normal morphologic aspects.
- Periesophageal lymph nodes:
- Number examined: 15
- Number positive for neoplasia: 03, without capsular involvement.
- Perigastric lymph nodes:
- Number examined: 11
- Number positive for neoplasia: 01, without capsular involvement.
- Other regional lymph nodes:
- Number examined: 01
- Number positive for neoplasia: 00

2 - "Esophageal margin":

- Uninvolved by carcinoma.

Primary Site Discrepancy		☒
ICD-O Discrepancy		☒
Site Discrepancy		☒

Source: NCI Genomic Data Commons file ebf6befe-9538-4693-8e84-a7c8e0a781ea (TCGA-VR-A8EP.3732C51B-D302-4877-A15C-2C5FBABC2264.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).